Surgical pathology report (de-identified scan), TCGA case TCGA-ZG-A9MC, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University Medical Center Hamburg-Eppendorf, specimen TCGA-ZG-A9MC-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

Histopathological Report

Adenocarcinoma NOS 8140/3

Date of cancer sample procurement:

Site: Prostate NOS C61.9

Date of pathology report:

Jan 11/2014

Patient ID:

Gross description:

1. (Prostate gland): Prostate gland: Weight: 60 g, Volume: 55 ml, Size: 5.1 x 5.2 x 4.2 cm. Adherent seminal vesicles and deferent duct: right side: 3.1 cm, left side: 2.8 cm. The surface is marked with green ink on the right side, blue ink on the left side. On the right recto-lateral surface a 4.2 x 1.2 x 1 cm measuring tissue defect marked with yellow ink. Total of the cross sections: 2.2 cm.
2. (Lymph nodes, right side): 5.2 x 3.9 x 1.5 cm measuring adipose tissue containing 9 nodes measuring up to 4.9 cm.
3. (Lymph nodes, left side): 6.1 x 3.9 x 1.6 cm measuring adipose tissue containing 3 nodes measuring up to 4.1 cm.

Microscopy:

1. Apex right and left: Right 6 tissue blocks, left 8 tissue blocks (total 14 tissue blocks). 4 cross sections: Right 20 tissue blocks, left 25 tissue blocks (total 45 tissue blocks). Basis right and left: Right 8 tissue blocks, left 8 tissue blocks (total 16 tissue blocks). Seminal vesicles right and left: Right 4 tissue blocks, left 3 tissue blocks (total 7 tissue blocks). Deferent ducts right and left: Right 1 tissue block, left 1 tissue block (total 2 tissue blocks).
2. Lymph nodes, right side: 15 tissue blocks.
3. Lymph nodes, left side: 8 tissue blocks.

Diagnosis:

1. (Prostate gland): Poorly differentiated prostatic adenocarcinoma, Gleason 5+4=9, (Gleason 5: 60%, Gleason 4: 35%, Gleason 3: 5%). Tumor involves both lobes with the main focus around the seminal vesicles. Maximum tumor diameter: 45 mm. Perineural invasion. Tumor infiltration into peri-prostatic adipose tissue in 8 tissue blocks with the main focus around the seminal vesicles (maximum invasion length 16 mm, maximal invasion depth 3.2 mm). Tumor infiltration into both seminal vesicles. Positive resection margins of the deferent ducts. Positive surgical margin mainly around the seminal vesicles (contact length 4.2 mm; Gleason 5+4).

Remaining prostatic tissue with small foci of prostatic intraepithelial neoplasia (high grade PIN) and signs of myoglandular hyperplasia of the prostate. Urothelium of the prostatic urethra without dysplasia.

2. (Lymph nodes, right side): Two lymph node metastases in nine lymph nodes (2/9).
3. (Lymph nodes, left side): Five tumor-free lymph nodes (0/5).

[page 2 of 2]
Tumor classification

(in consideration of the intraoperative frozen-section and immunohistochemical analyses):

pT3b, Gleason 5+4=9 (Gleason 5: 60%, Gleason 4: 35%, Gleason 3: 5%), maximum tumor diameter: 45 mm, tumor volume approx. 41 ml (Gleason 5: 24.6 ml, Gleason 4: 14.4 ml, Gleason 3: 2.0 ml), pN1 (2/14), L0*, V0, R1

Comments:

Positive surgical margin in tissue blocks AR2B, AL1B, R2D, BR4B, SBR1, SBR2, SBR3, SBR4, SBL1 and SBL3.

Tumor infiltration into peri-prostatic adipose tissue in blocks AR2B, SBR1, SBR2, SBR3, SBR4, SBL1, SBL2 and SBL3.

The preceding intraoperative frozen section revealed adenocarcinoma in the resection margin of the urethra.

The parallel sample showed tumor infiltration in the secondary resection of bladder neck dorsal, the secondary resection of the right ductus, the surgical margin right lateral, the secondary resection of Dennonvillier's fascia, apex and secondary resection of surgical margin of urethra.

*Immunohistochemical analyses (D2-40, CD31) on tissue blocks SBR1 and SBL1 revealed no lymphatic or venous invasion. However, due to the lymph node metastases earlier lymphatic invasion has to be assumed.

One macroscopic image for tumor mapping.

Source: NCI Genomic Data Commons file 70d4b4b6-b628-4530-822d-67a7e5e78964 (TCGA-ZG-A9MC.1B48B5AE-27A9-4D79-923C-14AF6DE4B4E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).